Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6920, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6920-01A (Primary Tumor).

Department of Cancer Pathology

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **Total organ resection – sigmoid colon**

Unit in charge:

Physician in charge:

Material collected on:

Material received

Expected time of examination:

Clinical diagnosis: **Cancer of the sigmoid colon.**

Examination performed on:

Macroscopic description:**A 18.2 cm length of large intestine with a segment of the mesentery sized 20.0 x 9.0 x 2.0 cm.****Ulcerous tumour sized 4.3 x 4.4 x 0.7 cm in the mucosa . The lesion surrounds 100% of the intestine circumference and narrows its lumen; it is located 12 cm from the incision line and 3.9 cm from the opposite one. The wall injected with blue dye. Outside the tumour, there is a 2 cm polyp and diverticula.**Microscopic description:**Adenocarcinoma tubulopapillare (G2).****Infiltratio carcinomatosa superficialis telae adiposae mesenterii. Incision lines free of neoplastic lesions. Off tumour: Adenoma tubulare cum dysplasia gradus mediocris (LG). Diverticula et diverticulitis Lymphonodulitis reactiva No V.**Histopathological Diagnosis:**Adenocarcinoma tubulopapillare coli. Tubulopapillar adenocarcinoma of the colon. (G2, Dukes B, Astler-Coller B2, pT3, pNO).**

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 3cd8c8de-2529-4c11-95bf-6d450a8ad959 (TCGA-D5-6920.785F1166-6B98-497A-9546-75CE66337309.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).